Surgical pathology report (de-identified scan), TCGA case TCGA-VQ-A8E7, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Barretos Cancer Hospital, specimen TCGA-VQ-A8E7-01B (Primary Tumor).

[page 1 of 2]
ICD-O-3
Adenocarcinoma, tubular
8211/3
Site: Gastroesophageal junction
C16.0
JL 3/20/14

Collect date:
(MM/DD/YYYY)

PATHOLOGY REPORT:

PRIMARY SITE: Stomach (Gastroesophageal junction)

I - "Esophagus + Stomach":

Adenocarcinoma characterized as follows:

Histological pattern(s) observed:
tubular

Histological grade:
II - moderately differentiated

Measure of the longest axis of the tumor: 12.70

Lauren's classification:

Ulceration:

present

Compromise of:

Mucosa

Muscularis mucosae

Submucosa

Muscularis propria

Adjacent adipose tissue

Type of tumor invasion

Spiculated

Inflammatory reaction:

Mild

Tumor implantation in peri-visceral adipose tissue:

Not detected

Proximal margin:

Free of neoplastic involvement.

Distal margin:

Free of neoplastic involvement.

Radial margin:

Free of neoplastic involvement.

Neural infiltration:

Present

Lymphatic vascular invasion:

Not detected

Sanguineous vascular invasion:

Present

[page 2 of 2]
Lymph nodes:

Compromised:

Compromised/dissected lymph nodes ratio: 1/23

Lymph node conglomerates:

Not detected

- Discrimination of lymph nodes:

. Periesophageal: 0/3

. Perigastric: 0/18

Note: the neoplasm is from esophagogastric transition. Intestinal pattern of Lauren.

2 - "Distal splenic artery (lymph node) " :

Absence of neoplasia in the examined materials (0/0).

3 - "Inferior paraesophageal lymph node":

Absence of neoplasia in the analyzed materials (0/0).

4 - "Recurrent lymph node :

Adenocarcinoma metastatic to lymph node (1/1).

5 - "Esophageal margin":

Free of neoplastic involvement.

6 - "Epiploon":

Free of neoplastic involvement.

PATHOLOGICAL STAGING

Topography	Morphology	Stage
Stomach, NOS	Adenocarcinoma, NOS	pT3 pN1

Criteria:	hw 10/24/13	Yes	No

Source: NCI Genomic Data Commons file fccbeacb-fe69-4d12-8e7c-77567876f3ab (TCGA-VQ-A8E7.45A33125-5E8A-43A6-AC05-1E747BAB6621.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).